Somatic mutation profile of tumor specimen C3N-03839-01 (aliquot CPT0236700008) from CPTAC case C3N-03839, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.6 years (19,956 days).
Specimen C3N-03839-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9db8422d-a671-44ec-bc5f-85e32034d826.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03839-31 (Blood Derived Normal), aliquot CPT0236770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35f162dc-db20-4107-8d52-f3524b423936

The open-access MAF lists 94 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 15, Intron 5, Nonsense Mutation 5, 3'Flank 2, Frame Shift Ins 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.4379dup p.N1460Kfs*2 | Frame Shift Ins (INS) | VAF 60/398 reads (15%) | catalogued as rs387906455; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 96/579 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 159/856 reads (19%) | catalogued as COSV99231552; called by muse, mutect2, varscan2
- ADAMTS17 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1287733938; called by muse, mutect2
- APC2 | c.6803C>T p.A2268V | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs777883453; called by muse, mutect2, varscan2
- ATP10A | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 110/540 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764757185, COSV100790726; called by muse, mutect2, varscan2
- AVPR2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 163/451 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as rs782790439; called by muse, mutect2, varscan2
- BTNL2 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 53/542 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs376819015; called by muse, mutect2, varscan2
- C10orf71 | c.4181C>T p.P1394L | Missense Mutation (SNP) | VAF 127/797 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs565274702, COSV60510894; called by muse, mutect2, varscan2
- CALHM1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 92/647 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs769331766; called by muse, mutect2, varscan2
- CDKL5 | c.2340C>G p.F780L | Missense Mutation (SNP) | VAF 135/457 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV101184194; called by muse, mutect2, varscan2
- CELSR3 | c.6356C>A p.A2119D | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.143); catalogued as COSV99372387; called by muse, mutect2, varscan2
- CLSTN2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 99/736 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.971); catalogued as rs765719211, COSV71720759; called by muse, mutect2, varscan2
- CSMD3 | c.7733G>C p.G2578A (on ENST00000297405 / NM_001363185.1; = p.G2474A on NM_052900.3) | Missense Mutation (SNP) | VAF 205/746 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52177476; called by muse, mutect2, varscan2
- CTNNB1 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs77624106; called by muse, mutect2, varscan2
- F11 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 110/751 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs748139184, CM035505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO21 | c.65C>A p.P22Q | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.199); catalogued as rs1190913010; called by muse, mutect2, varscan2
- GPR50 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1288793743, COSV54436783; called by muse, mutect2, varscan2
- IFFO2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 105/716 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs979878869, COSV69085783; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 109/946 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs752634292, COSV61212237; called by muse, mutect2, varscan2
- IL31RA | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 127/946 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs765709220; called by muse, mutect2, varscan2
- INF2 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 80/540 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs373532334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L1CAM | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 130/1020 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1557090232, COSV62827427, COSV62827938; called by muse, mutect2, varscan2
- LRRC10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 83/491 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs768421373, COSV100825446, COSV64060146; called by muse, mutect2, varscan2
- LRRC30 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67301533; called by muse, mutect2, varscan2
- MYO1F | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 134/769 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778366731; called by muse, mutect2, varscan2
- NRXN2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 172/1117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1164192972, COSV55454599; called by muse, mutect2, varscan2
- RBFOX1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs761205127, COSV60956442; called by muse, mutect2
- SEZ6 | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 106/648 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.052); catalogued as rs531592765; called by muse, mutect2, varscan2
- SHROOM2 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs748501801; called by muse, mutect2, varscan2
- SLC6A7 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1299240222; called by muse, mutect2, varscan2
- THOC6 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 37/244 reads (15%) | catalogued as rs1194408714; called by muse, mutect2, varscan2
- TMTC2 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.514); catalogued as rs760933625, COSV58262981; called by muse, mutect2, varscan2
- TRIM62 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 135/837 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52221226; called by muse, mutect2, varscan2
- TRPM6 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 131/739 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202053435, COSV62506882; called by muse, mutect2, varscan2
- TSPYL4 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | catalogued as rs75652959; called by muse, mutect2, varscan2
- TTN | c.5255G>A p.R1752H (on ENST00000591111; = p.R1706H on NM_003319.4) | Missense Mutation (SNP) | VAF 56/366 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs150737838, COSV59901601; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UGGT2 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs780935476; called by muse, mutect2, varscan2
- UNC79 | c.1574G>A p.R525Q (on ENST00000393151 / NM_001346218.2; = p.R348Q on NM_020818.5) | Missense Mutation (SNP) | VAF 98/562 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs200477456, COSV99825931; called by muse, mutect2, varscan2
- VPS13B | c.11245G>A p.E3749K | Missense Mutation (SNP) | VAF 140/486 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs180177372, CM062024; called by muse, mutect2, varscan2
- ZBED9 | c.3795A>C p.L1265F | Missense Mutation (SNP) | VAF 105/522 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.696); catalogued as rs757920531; called by muse, mutect2, varscan2
- ZNF536 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs556954524, COSV62824617, COSV62826657; called by muse, mutect2, varscan2
- ABCA7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ABCC8 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 190/1017 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AC013489.1 | c.1565T>G p.F522C | Missense Mutation (SNP) | VAF 145/622 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 109/679 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFF2 | c.2423A>T p.D808V | Missense Mutation (SNP) | VAF 178/567 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- AXDND1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 65/450 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C8A | c.1751G>T p.C584F | Missense Mutation (SNP) | VAF 88/608 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT8 | c.1196dup p.K400Qfs*7 | Frame Shift Ins (INS) | VAF 34/206 reads (17%) | called by mutect2, pindel, varscan2
- CSNK1G3 | c.1327A>C p.I443L | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG2 | c.1528T>C p.S510P | Missense Mutation (SNP) | VAF 120/779 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GUCY2F | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 222/601 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDLBP | c.3008A>T p.E1003V | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- IGSF10 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IL13RA2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- LAMC3 | c.1376G>A p.C459Y | Missense Mutation (SNP) | VAF 186/1227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKRN3 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 49/425 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP20 | c.1146T>G p.I382M | Missense Mutation (SNP) | VAF 78/498 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAALAD2 | c.696T>A p.Y232* | Nonsense Mutation (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- NBN | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 140/633 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PLXNA3 | c.2633G>T p.G878V | Missense Mutation (SNP) | VAF 57/481 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO3 | c.3986C>T p.P1329L | Missense Mutation (SNP) | VAF 106/632 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, varscan2
- SHOC1 | c.2971T>C p.S991P | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SPOCK1 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated, low confidence (0.77); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- TMIGD2 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 44/372 reads (12%) | called by muse, mutect2, varscan2
- ZMYM6 | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF557 | c.1117G>A p.D373N (on ENST00000414706 / NM_001044388.2; = p.D380N on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/460 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF655 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF75D | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 41/493 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ADH5 | c.1071A>G p.K357= | Silent (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5187C>T p.A1729= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as rs770331336, COSV56354446; called by muse, mutect2, varscan2
- C2orf42 | c.1635G>A p.R545= | Silent (SNP) | VAF 186/1134 reads (16%) | called by muse, mutect2, varscan2
- DMRT2 | c.1059C>T p.T353= | Silent (SNP) | VAF 60/384 reads (16%) | catalogued as rs564464685; called by muse, mutect2, varscan2
- EPHB1 | c.1641G>A p.A547= | Silent (SNP) | VAF 65/527 reads (12%) | catalogued as rs776531462, COSV101212909, COSV67670208; called by muse, mutect2, varscan2
- HOXA11 | c.303C>T p.G101= | Silent (SNP) | VAF 62/433 reads (14%) | catalogued as COSV50053023; called by muse, varscan2
- KCNA5 | c.861G>A p.A287= | Silent (SNP) | VAF 120/684 reads (18%) | catalogued as COSV52907103; called by muse, mutect2, varscan2
- LGR6 | c.510C>T p.D170= (on ENST00000367278 / NM_001017403.1; = p.D118= on NM_021636.3) | Silent (SNP) | VAF 46/407 reads (11%) | catalogued as rs373499034; called by muse, mutect2, varscan2
- MBD5 | c.3060A>G p.R1020= | Silent (SNP) | VAF 73/580 reads (13%) | called by muse, mutect2, varscan2
- OPALIN | c.138G>A p.V46= | Silent (SNP) | VAF 54/424 reads (13%) | catalogued as rs1464216961; called by muse, mutect2, varscan2
- PINK1 | c.738A>T p.R246= | Silent (SNP) | VAF 164/1037 reads (16%) | called by muse, mutect2, varscan2
- RAPSN | c.483C>T p.L161= | Silent (SNP) | VAF 91/581 reads (16%) | catalogued as rs754775068; called by muse, mutect2, varscan2
- SLC25A44 | c.717C>T p.L239= | Silent (SNP) | VAF 68/437 reads (16%) | catalogued as rs764738266, COSV100849321; called by muse, mutect2, varscan2
- TFAP2C | c.540C>T p.V180= | Silent (SNP) | VAF 92/620 reads (15%) | called by muse, mutect2, varscan2
- ZNF230 | c.483C>T p.F161= | Silent (SNP) | VAF 169/569 reads (30%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976622 T>G | 3'Flank (SNP) | VAF 4/13 reads (31%) | catalogued as rs753668255; called by muse, varscan2
- C2 | c.443-1124G>A | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs1406448907; called by muse, mutect2
- DENND10P1 | n.675G>T | RNA (SNP) | VAF 412/1255 reads (33%) | called by muse, mutect2, varscan2
- IMPDH2 | c.98+17C>T | Intron (SNP) | VAF 75/527 reads (14%) | called by muse, mutect2, varscan2
- MON2 | chr12:62602955 C>T | 3'Flank (SNP) | VAF 57/402 reads (14%) | catalogued as rs1373842422; called by muse, mutect2, varscan2
- NEMF | c.2466-296C>T | Intron (SNP) | VAF 42/324 reads (13%) | called by muse, mutect2, varscan2
- RGS3 | c.3081-288G>C | Intron (SNP) | VAF 75/469 reads (16%) | called by muse, mutect2, varscan2
- SERPINH1 | c.-28C>T | 5'UTR (SNP) | VAF 132/713 reads (19%) | called by muse, mutect2, varscan2
- TPM3 | c.643-13A>G | Intron (SNP) | VAF 64/360 reads (18%) | called by muse, mutect2, varscan2
